Somatic mutation profile of tumor specimen ALCH-B1MS-TTP1-A (aliquot ALCH-B1MS-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1MS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 78.7 years (28,762 days).
Specimen ALCH-B1MS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5774092-0442-468a-be2f-242f4ab46cc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MS-NB1-A (Blood Derived Normal), aliquot ALCH-B1MS-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83ccf4eb-ed14-4845-837e-4444c79bd399

The open-access MAF lists 1,396 somatic variants for this specimen: 936 protein-altering or splice-affecting, 288 silent, 172 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 807, Silent 288, Intron 87, Nonsense Mutation 75, Splice Site 27, 5'UTR 25, RNA 23, 3'UTR 21, 5'Flank 13, Frame Shift Del 13, Splice Region 10, Frame Shift Ins 3.

Variants (750 of 1,396; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYCR2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs876657403, CM154025; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT3 | c.1868G>T p.W623L | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs786205503, CM162331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 34/239 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593409; called by muse, mutect2
- ABCB1 | c.3231C>G p.S1077R | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55948456; called by muse, mutect2, varscan2
- ABCC3 | c.1173G>C p.R391S | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53324298; called by muse, mutect2
- ABL1 | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59342753; called by muse, mutect2, varscan2
- AC006059.2 | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 57/415 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV59609165; called by muse, mutect2, varscan2
- ADGRG4 | c.5730G>T p.E1910D | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV54953155; called by muse, mutect2, varscan2
- ADGRL3 | c.2168G>T p.R723I (on ENST00000506720 / NM_001322402.2; = p.R655I on NM_015236.6) | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101546910; called by muse, mutect2
- ALDH1A2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51087136, COSV99990775; called by muse, mutect2
- ALX4 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs754942746; called by mutect2, varscan2
- AMY2B | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 102/744 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV63716994; called by muse, mutect2, varscan2
- ANGPT1 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 28/418 reads (7%) | catalogued as COSV52445707; called by muse, mutect2
- APBB1 | c.321del p.L108Wfs*6 | Frame Shift Del (DEL) | VAF 20/214 reads (9%) | catalogued as COSV54972798; called by pindel, varscan2
- ARHGEF2 | c.2348G>A p.R783Q (on ENST00000361247 / NM_001162383.2; = p.R755Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.629); catalogued as rs776739832, COSV58112823; called by mutect2, varscan2
- ARID2 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57607042; called by muse, mutect2
- ARMC8 | c.253G>A p.V85M (on ENST00000469044 / NM_001363941.2; = p.V71M on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1471789297; called by muse, mutect2
- ASB5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV56668815, COSV56670712; called by muse, mutect2
- ASXL3 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as rs1461782055, COSV99324105; called by muse, mutect2
- AXIN2 | c.2139G>T p.Q713H | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs752664902; called by muse, varscan2
- BCHE | c.1329T>A p.N443K | Missense Mutation (SNP) | VAF 50/563 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs570544890; called by muse, mutect2
- BCL2L1 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56967123; called by muse, mutect2, varscan2
- BNC2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1286876952, COSV66141539; called by muse, mutect2
- BORCS8 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV50761703; called by muse, mutect2
- BPGM | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV104421063; called by muse, mutect2, varscan2
- BRCA1 | c.2958C>G p.I986M | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV58801178; called by muse, mutect2
- BRINP3 | c.2069C>A p.P690H | Missense Mutation (SNP) | VAF 52/260 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66540255; called by muse, mutect2, varscan2
- C12orf54 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV100011493; called by muse, mutect2
- C5orf49 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs750048060, COSV57874822; called by muse, mutect2, varscan2
- C8orf48 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 34/543 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52046869; called by muse, mutect2
- CA4 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs1245199379, CM104926, COSV56282111; called by muse, mutect2, varscan2
- CACNA1B | c.4351C>T p.R1451W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201000023, COSV53125838; called by muse, mutect2, varscan2
- CACNA1E | c.3838G>A p.D1280N | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV62386084, COSV62399059; called by muse, mutect2
- CASR | c.2377G>A p.E793K (on ENST00000490131; = p.E870K on NM_000388.4) | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as CM165756, COSV56140927, COSV99948461; called by muse, mutect2
- CATSPER4 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs765697791; called by mutect2, varscan2
- CBR4 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100085758, COSV60370400; called by muse, mutect2
- CCDC168 | c.16048G>T p.V5350F | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.945); catalogued as COSV59422591; called by muse, mutect2, varscan2
- CCN4 | c.481C>A p.R161S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.38); catalogued as COSV51534877; called by muse, mutect2, varscan2
- CCNB3 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.354); catalogued as COSV99328391; called by muse, mutect2
- CD163L1 | c.3887T>A p.L1296Q | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV58021771; called by muse, mutect2
- CD3E | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62346786; called by muse, mutect2
- CDH23 | c.5328C>A p.N1776K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs371522191, COSV99824436; ClinVar: uncertain significance; called by mutect2, varscan2
- CDH6 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54065001; called by muse, mutect2, varscan2
- CDHR1 | c.1457del p.P486Qfs*22 | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | catalogued as COSV60565360; called by mutect2, varscan2
- CERS3 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52568754; called by muse, mutect2
- CFAP45 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776738795, COSV63648389; called by muse, mutect2, varscan2
- CFAP47 | c.7223G>T p.G2408V | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66217773; called by muse, mutect2
- CFAP47 | c.8344A>G p.S2782G | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1268411103, COSV66221442; called by muse, mutect2
- CFHR1 | c.145del p.E49Kfs*22 | Frame Shift Del (DEL) | VAF 59/392 reads (15%) | catalogued as COSV57628032; called by mutect2, pindel, varscan2
- CHD1 | c.3161G>C p.R1054P | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV99399009; called by muse, mutect2, varscan2
- CHD4 | c.5293G>C p.E1765Q (on ENST00000357008 / NM_001363606.2; = p.E1776Q on NM_001273.5) | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58897080; called by muse, mutect2
- CNTN2 | c.2717C>A p.T906K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as COSV100085587; called by muse, mutect2
- COL11A1 | c.4402G>T p.G1468W | Missense Mutation (SNP) | VAF 48/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62172309, COSV62172451; called by muse, mutect2, varscan2
- COL12A1 | c.823+1G>T p.X275_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | catalogued as COSV99072112; called by muse, mutect2
- COL24A1 | c.1921C>A p.R641S | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV65310470; called by muse, mutect2
- COL6A6 | c.3329C>T p.T1110I | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs758826093; called by muse, mutect2, varscan2
- CPE | c.1198C>A p.H400N | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868366203; called by muse, mutect2
- CRCP | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.299); catalogued as COSV58534533; called by muse, mutect2, varscan2
- CSMD3 | c.5924C>A p.A1975D (on ENST00000297405 / NM_001363185.1; = p.A1871D on NM_052900.3) | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV52115153; called by muse, mutect2
- CSMD3 | c.5510G>C p.G1837A (on ENST00000297405 / NM_001363185.1; = p.G1733A on NM_052900.3) | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52309266; called by muse, mutect2
- CYP4F11 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99931146; called by muse, mutect2, varscan2
- DDB1 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57101932; called by muse, mutect2, varscan2
- DDC | c.876G>A p.E292= | Splice Region (SNP) | VAF 51/444 reads (11%) | catalogued as CS1010479; called by muse, mutect2, varscan2
- DEFB110 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV67017998; called by muse, mutect2, varscan2
- DGKB | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as rs1453528058; called by muse, mutect2
- DMRTA1 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865992039; called by muse, mutect2, varscan2
- DNAH11 | c.10540C>A p.L3514M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100179582; called by muse, mutect2, varscan2
- DNAH9 | c.4198G>T p.D1400Y | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99306750; called by muse, mutect2, varscan2
- DPP10 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59662567; called by muse, mutect2, varscan2
- DSEL | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as rs1168942390; called by muse, mutect2
- DSEL | c.1874A>T p.K625M | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV59490499, COSV59490917; called by muse, mutect2
- DSN1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | catalogued as COSV65518776; called by muse, mutect2
- EBLN1 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs1419257319; called by muse, mutect2
- ECT2L | c.1349G>T p.C450F | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100871819; called by muse, mutect2
- EPHB1 | c.1967G>C p.G656A | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67674541; called by muse, mutect2, varscan2
- EVC2 | c.2374G>T p.E792* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as COSV100184857; called by muse, mutect2
- EYA2 | c.534C>A p.Y178* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV57946670; called by muse, mutect2, varscan2
- F5 | c.2897C>T p.T966I | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); catalogued as rs370330489; called by muse, mutect2, varscan2
- FAP | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51862741; called by muse, mutect2, varscan2
- FAT3 | c.7687C>A p.P2563T | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.428); catalogued as COSV99966827; called by muse, mutect2
- FCRL3 | c.1600_1601del p.L534Dfs*11 | Frame Shift Del (DEL) | VAF 62/406 reads (15%) | catalogued as rs1292617851; called by pindel, varscan2
- FGD1 | c.1257C>A p.H419Q | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV64309522; called by muse, mutect2
- FGFR2 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 50/629 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV100337144; called by muse, mutect2
- FILIP1 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs867896706; called by muse, mutect2
- FKBP3 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53533552; called by muse, mutect2, varscan2
- FLG | c.5621C>A p.S1874* | Nonsense Mutation (SNP) | VAF 30/390 reads (8%) | catalogued as COSV64245171; called by muse, mutect2
- FOXO4 | c.880G>T p.G294W | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100446990; called by muse, mutect2, varscan2
- FREM1 | c.1444C>G p.R482G | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as COSV66527246; called by muse, mutect2
- FRK | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV73384273; called by muse, mutect2
- FSCB | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.225); catalogued as COSV61219016; called by muse, varscan2
- FUT3 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as rs777657616; called by muse, mutect2, varscan2
- GABRG1 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954790; called by muse, mutect2
- GAD2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV99394035; called by muse, mutect2
- GCKR | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53106845; called by muse, mutect2
- GCN1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56102972; called by muse, mutect2
- GDF5 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs1158506896; called by muse, mutect2
- GLCCI1 | c.1111del p.C371Vfs*56 | Frame Shift Del (DEL) | VAF 39/274 reads (14%) | catalogued as COSV56200575; called by mutect2, pindel, varscan2
- GLIS3 | c.1922A>C p.Y641S | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs749485361; called by muse, mutect2
- GNAS | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs779343437; called by muse, mutect2, varscan2
- GRIK2 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59761669, COSV59769104; called by muse, mutect2
- GSG1L | c.878G>C p.R293P (on ENST00000447459 / NM_001109763.2; = p.R138P on NM_144675.2) | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); catalogued as COSV66582627; called by muse, mutect2
- HADHA | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 33/495 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM985540; called by muse, mutect2
- HDAC9 | c.2125G>T p.G709* | Nonsense Mutation (SNP) | VAF 55/448 reads (12%) | catalogued as COSV67787068, COSV67787669; called by muse, mutect2, varscan2
- HERC5 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52040906; called by muse, mutect2
- HHIPL2 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58568350; called by muse, mutect2, varscan2
- HMCN2 | c.5764C>T p.P1922S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs1035842571; called by muse, mutect2, varscan2
- HMGB4 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs777407060; called by muse, mutect2
- HMGXB4 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV53336392; called by muse, varscan2
- HOXA7 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1449685607, COSV54217425; called by muse, varscan2
- HOXB13 | c.649C>A p.R217S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51704895, COSV99284849; called by muse, mutect2
- HUWE1 | c.12448G>A p.D4150N | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53359894, COSV53369009; called by muse, mutect2
- IFI44L | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779556259; called by muse, mutect2, varscan2
- IFNA2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs1165251795; called by muse, mutect2, varscan2
- IGHD | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.372); catalogued as COSV101162818; called by muse, mutect2, varscan2
- IGSF11 | c.521C>A p.P174Q (on ENST00000393775 / NM_001015887.3; = p.P173Q on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100677451; called by muse, mutect2, varscan2
- IHO1 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV56507831; called by muse, mutect2
- IL17F | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60234029; called by muse, mutect2, varscan2
- IL1R2 | c.1121A>T p.K374I | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1316912445; called by muse, mutect2, varscan2
- IMPG1 | c.2079C>A p.C693* | Nonsense Mutation (SNP) | VAF 28/227 reads (12%) | catalogued as COSV63113121; called by muse, mutect2, varscan2
- INTS5 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV57952238; called by muse, mutect2, varscan2
- ITGA7 | c.1087G>T p.G363C (on ENST00000555728; = p.G319C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV99144232; called by muse, mutect2
- ITIH5 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 36/518 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as rs1385297621, COSV99905505; called by muse, mutect2
- ITPR1 | c.4397G>T p.S1466I (on ENST00000354582; = p.S1451I on NM_002222.7) | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs1206311675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPRID1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV60078044; called by muse, mutect2
- IZUMO1R | c.176C>A p.T59K | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs374445245; called by muse, mutect2, varscan2
- JPH1 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM150143, COSV60608883; called by mutect2, varscan2
- KAZN | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.921); catalogued as rs138289296; called by muse, mutect2, varscan2
- KCNA1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 15/146 reads (10%) | catalogued as COSV66837992; called by muse, mutect2, varscan2
- KCND2 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 96/564 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV58576011; called by mutect2, varscan2
- KCNK15 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1197326781; called by muse, mutect2
- KCNMA1 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 56/756 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as COSV54229767; called by muse, mutect2
- KDR | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545112274, COSV55763636, COSV55771570; called by muse, mutect2
- KEAP1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV50648926; called by muse, mutect2, varscan2
- KEL | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV62336463; called by muse, mutect2
- KIAA1755 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 28/184 reads (15%) | catalogued as COSV54073819; called by muse, varscan2
- KL | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs766859418, COSV66309334; called by muse, mutect2, varscan2
- KLHL32 | c.1068G>T p.E356D | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.127); catalogued as COSV65112214; called by muse, mutect2
- KMT2A | c.10893A>T p.E3631D | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs113003878; called by mutect2, varscan2
- KNCN | c.259G>A p.G87R (on ENST00000481882 / NM_001322255.2; = p.G64R on NM_001097611.1) | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1460738844, COSV99606362; called by muse, mutect2, varscan2
- KRT33A | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144929; called by muse, mutect2, varscan2
- LDB2 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58782604; called by muse, mutect2
- LETM1 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV57104504; called by muse, mutect2
- LMAN1L | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1225855329, COSV59000845; called by muse, mutect2, varscan2
- LRP1B | c.12075G>T p.M4025I | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs867479053; called by muse, mutect2, varscan2
- LRRC40 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100918804; called by muse, mutect2
- LSAMP | c.771G>T p.R257S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61310942; called by muse, mutect2
- LVRN | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1477961706; called by muse, mutect2, varscan2
- M1AP | c.1244C>A p.P415H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs895348981; called by muse, mutect2, varscan2
- MAGEE2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 14/320 reads (4%) | catalogued as COSV64898597; called by muse, mutect2
- MBD4 | c.997A>T p.I333L | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs994641746, COSV51443973; called by muse, mutect2, varscan2
- MED1 | c.1046C>G p.S349* | Nonsense Mutation (SNP) | VAF 24/376 reads (6%) | catalogued as COSV56127261, COSV56127700; called by muse, mutect2
- MED12 | c.2140C>A p.P714T | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as rs1487824889; called by muse, mutect2, varscan2
- MEOX2 | c.763C>G p.R255G | Missense Mutation (SNP) | VAF 64/560 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV56287712; called by muse, mutect2, varscan2
- MOV10 | c.505T>C p.F169L | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs753482453; called by muse, mutect2, varscan2
- MRFAP1 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV57995345; called by muse, mutect2, varscan2
- MTCP1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.72); catalogued as rs1557291959; called by muse, mutect2
- MTRNR2L1 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as rs564074737; called by muse, varscan2
- MUC16 | c.38539C>A p.P12847T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.251); catalogued as COSV101198492; called by muse, mutect2, varscan2
- MUC16 | c.9226C>A p.L3076M | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.062); catalogued as COSV67462689, COSV67466619; called by muse, mutect2, varscan2
- MUC17 | c.5299A>G p.S1767G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as rs745799755; called by muse, mutect2, varscan2
- MUC17 | c.12328A>T p.T4110S | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV100071873; called by muse, mutect2
- MUC4 | c.2183G>A p.G728E | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs537035043; called by muse, mutect2
- MUC4 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV62158648; called by muse, mutect2
- MUC5AC | c.14278G>A p.V4760M | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs374724880, COSV100611634; called by muse, varscan2
- MYBPC1 | c.2528G>C p.R843T (on ENST00000550270 / NM_206820.2; = p.R850T on NM_002465.4) | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62252739; called by muse, mutect2
- MYF6 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1281930067, COSV99952714; called by muse, mutect2
- MYH3 | c.4138G>C p.A1380P | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56862921; called by muse, mutect2, varscan2
- MYL2 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 26/527 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99960889; called by muse, mutect2
- NARF | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as rs367598656; called by muse, mutect2, varscan2
- NCOR2 | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62297618; called by muse, mutect2
- NES | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 69/439 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV63960717; called by muse, mutect2, varscan2
- NKAIN2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 12/266 reads (5%) | catalogued as COSV63644046; called by muse, mutect2
- NLRP12 | c.828C>A p.S276R | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.351); catalogued as COSV60753804; called by muse, mutect2, varscan2
- NLRP13 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 73/260 reads (28%) | catalogued as COSV61622931; called by muse, mutect2, varscan2
- NLRP13 | c.601C>G p.H201D | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV61619688, COSV61623369; called by muse, mutect2, varscan2
- NUDT10 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62854653; called by muse, mutect2, varscan2
- NUP133 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs762406885, COSV54569096; called by muse, mutect2, varscan2
- OAS3 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57449030; called by muse, mutect2
- OLFM3 | c.616T>A p.L206M (on ENST00000338858 / NM_001288821.1; = p.L186M on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV58798828; called by muse, mutect2, varscan2
- OPHN1 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100830858; called by muse, mutect2
- OR10J5 | c.166del p.H56Tfs*8 | Frame Shift Del (DEL) | VAF 33/319 reads (10%) | catalogued as COSV58387166; called by mutect2, pindel, varscan2
- OR1N1 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201017792; called by muse, mutect2, varscan2
- OR1S1 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58707027; called by muse, mutect2, varscan2
- OR2M7 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV58739969; called by muse, mutect2, varscan2
- OR4K1 | c.393C>A p.H131Q | Missense Mutation (SNP) | VAF 49/542 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV53461367; called by muse, mutect2
- OR4K5 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 54/880 reads (6%) | catalogued as COSV60003976; called by muse, mutect2
- OR51L1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV58624630; called by muse, mutect2, varscan2
- OR51V1 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV58316119; called by muse, mutect2, varscan2
- OR52E4 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57623914; called by muse, mutect2, varscan2
- OR7D4 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58071364; called by muse, mutect2, varscan2
- P2RY10 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV50681389; called by muse, mutect2, varscan2
- PAEP | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52986262; called by muse, mutect2, varscan2
- PAK4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.478); catalogued as rs376845802; called by muse, mutect2
- PCCB | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52444049; called by muse, mutect2
- PCDH15 | c.4031A>T p.Y1344F | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV57375785; called by muse, mutect2
- PCDHA4 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV100793439; called by muse, mutect2
- PCDHB1 | c.1547C>A p.A516E | Missense Mutation (SNP) | VAF 41/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60630920, COSV60633681; called by muse, mutect2, varscan2
- PCDHB10 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 55/507 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV53381710; called by muse, mutect2, varscan2
- PDE6C | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.917); catalogued as rs1459501579; called by muse, mutect2
- PDE7B | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99066784; called by muse, mutect2
- PDE8B | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs144019309, COSV53737870; called by muse, mutect2, varscan2
- PDZD11 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV52105343; called by muse, mutect2
- PDZRN3 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55207853; called by muse, mutect2, varscan2
- PENK | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as COSV59240641; called by muse, mutect2, varscan2
- PHKG2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.654); catalogued as COSV60314202; called by muse, mutect2
- PHRF1 | c.3829G>A p.D1277N (on ENST00000264555 / NM_001286581.2; = p.D1276N on NM_020901.4) | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1017678288, COSV52753089, COSV52759443; called by muse, mutect2
- PIK3C2A | c.2099G>T p.W700L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56407257; called by muse, mutect2, varscan2
- PIKFYVE | c.3792G>A p.R1264= | Splice Region (SNP) | VAF 24/298 reads (8%) | catalogued as rs774727332; called by muse, mutect2
- PLAG1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57610227; called by muse, mutect2
- PLCL1 | c.2605G>T p.V869F | Missense Mutation (SNP) | VAF 63/440 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs1224507318; called by muse, mutect2, varscan2
- PLEKHA1 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs200256740; called by muse, mutect2
- PNN | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as rs781653328; called by muse, mutect2
- POLQ | c.3608A>T p.Q1203L | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV99951784; called by muse, varscan2
- POT1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV62929696; called by muse, mutect2
- PPID | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 25/273 reads (9%) | catalogued as COSV56987771; called by muse, mutect2
- PPM1E | c.2039G>T p.R680I | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV57572405; called by muse, mutect2
- PPP1R9A | c.1650-1G>C p.X550_splice | Splice Site (SNP) | VAF 23/243 reads (9%) | catalogued as COSV56912053, COSV99194894; called by muse, mutect2, varscan2
- PRAMEF12 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs774046599, COSV100743080; called by muse, mutect2, varscan2
- PRAMEF12 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.66); catalogued as COSV63215258; called by muse, mutect2
- PREP | c.1384G>T p.D462Y (on ENST00000369110; = p.D528Y on NM_002726.5) | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64872314; called by muse, mutect2
- PRKAR1A | c.550-1G>T p.X184_splice | Splice Site (SNP) | VAF 72/507 reads (14%) | catalogued as CD043416, COSV104423131; called by muse, mutect2, varscan2
- PRUNE2 | c.2392C>A p.P798T | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV100944362; called by muse, mutect2, varscan2
- PTCHD3 | c.417G>T p.W139C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV101438907; called by mutect2, varscan2
- RABEP1 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 70/429 reads (16%) | catalogued as COSV52584796; called by muse, mutect2, varscan2
- RASGRP3 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as rs1260562029; called by muse, mutect2
- RB1 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 89/669 reads (13%) | catalogued as CM063090, COSV57312413; called by muse, mutect2, varscan2
- RBM10 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV52101874; called by muse, mutect2
- RBM26 | c.2566G>T p.G856C (on ENST00000438737 / NM_001366735.2; = p.G829C on NM_022118.5) | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57401076; called by muse, mutect2, varscan2
- RHAG | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57705575; called by muse, mutect2, varscan2
- RHBDD1 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV58125633; called by muse, mutect2, varscan2
- RHPN2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 70/358 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs772227567; called by muse, varscan2
- RNF157 | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771199748; called by muse, mutect2, varscan2
- RPE65 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.169); catalogued as COSV99253926; called by muse, mutect2
- RPE65 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 55/525 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.159); catalogued as rs375611153; called by muse, mutect2, varscan2
- RUNX1T1 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as COSV56139069; called by muse, mutect2
- RYR2 | c.6218C>A p.S2073Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV63679042; called by muse, mutect2
- SACS | c.11425G>A p.E3809K | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.787); catalogued as COSV66542488; called by muse, mutect2
- SAMD9L | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1209009941; called by muse, mutect2
- SCN3A | c.1478C>A p.S493Y | Missense Mutation (SNP) | VAF 61/542 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV51819889; called by muse, mutect2, varscan2
- SCN4A | c.4457G>A p.G1486D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1567816424; called by muse, mutect2
- SCYL2 | c.1342A>T p.S448C | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); catalogued as rs928099602; called by muse, mutect2
- SEC16A | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1484772553; called by muse, mutect2
- SENP7 | c.187-1G>T p.X63_splice | Splice Site (SNP) | VAF 30/184 reads (16%) | catalogued as rs1301510565; called by mutect2, varscan2
- SEPTIN14 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs753768896, COSV66427733; called by muse, mutect2, varscan2
- SETD2 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs751617319; called by muse, mutect2, varscan2
- SETD7 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs769809052; called by mutect2, varscan2
- SI | c.4098C>A p.F1366L | Missense Mutation (SNP) | VAF 63/515 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.232); catalogued as COSV52278197; called by muse, mutect2, varscan2
- SI | c.2819G>T p.R940I | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV52273763; called by muse, mutect2
- SIGLEC10 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV59482671; called by muse, mutect2, varscan2
- SKAP1 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.835); catalogued as COSV61149614; called by muse, mutect2
- SLAMF8 | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 40/418 reads (10%) | catalogued as COSV56987795; called by muse, mutect2
- SLC22A3 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51715421; called by muse, mutect2
- SLC39A12 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV99075542; called by muse, mutect2
- SLC5A1 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 34/336 reads (10%) | catalogued as COSV56682874, COSV56684233; called by muse, mutect2
- SLC8A3 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770234490; called by muse, mutect2
- SLFN5 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867983260; called by muse, mutect2
- SLIT2 | c.1384C>A p.R462S | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56588499; called by muse, mutect2
- SLITRK3 | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV53852188; called by muse, varscan2
- SORCS1 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV53868586; called by muse, mutect2
- SPANXN3 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as COSV65140857; called by muse, mutect2
- SPATA13 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57978688; called by muse, mutect2, varscan2
- SPATA16 | c.900G>C p.E300D | Missense Mutation (SNP) | VAF 66/870 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100651508, COSV63527383; called by muse, mutect2
- SPATA31D1 | c.4554G>T p.M1518I | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV61192579; called by muse, mutect2, varscan2
- ST18 | c.1389C>A p.D463E | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52486856; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | PolyPhen possibly damaging (0.763); catalogued as rs769227304, COSV100085851; called by mutect2, varscan2
- STON2 | c.1135G>C p.D379H (on ENST00000649389 / NM_001366849.2; = p.D322H on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99964821; called by muse, varscan2
- STXBP5L | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV56510444; called by muse, varscan2
- TAF1 | c.3585A>T p.Q1195H (on ENST00000373790 / NM_138923.4; = p.Q1216H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as CS1513568; called by muse, mutect2
- TCF4 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61903804; called by muse, mutect2
- TEK | c.1910-2A>T p.X637_splice | Splice Site (SNP) | VAF 17/339 reads (5%) | catalogued as COSV101193082; called by muse, mutect2
- TFCP2L1 | c.898G>T p.V300L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV55291172; called by muse, mutect2, varscan2
- TFG | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs765052576; called by muse, varscan2
- TGFBR2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 41/226 reads (18%) | catalogued as COSV55448402; called by muse, mutect2, varscan2
- TLL1 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777194759; called by muse, mutect2
- TLR10 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs189663400, COSV100457445; called by muse, mutect2
- TNNT3 | c.278G>A p.R93Q (on ENST00000397301 / NM_001367846.1; = p.R82Q on NM_006757.4) | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415991336; called by muse, mutect2, varscan2
- TNR | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as rs1237863350, COSV54885054; called by muse, mutect2, varscan2
- TRIM58 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825003, COSV100825218, COSV63569534; called by muse, mutect2, varscan2
- TRIP11 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 56/842 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs770551258, COSV50913425; called by muse, mutect2
- TRPM3 | c.653C>A p.A218E (on ENST00000357533 / NM_001366142.2; = p.A63E on NM_020952.6) | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs140438424; called by muse, mutect2, varscan2
- TRPM4 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53262856; called by muse, varscan2
- TSGA10 | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs769926254; called by muse, mutect2, varscan2
- TTN | c.84728C>A p.A28243D (on ENST00000591111; = p.A20819D on NM_003319.4) | Missense Mutation (SNP) | VAF 35/325 reads (11%) | PolyPhen benign (0.049); catalogued as COSV60043593; called by muse, mutect2, varscan2
- TUBB8 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV59118239; called by muse, mutect2
- TXNDC2 | c.834G>T p.Q278H (on ENST00000306084 / NM_001098529.2; = p.Q211H on NM_032243.6) | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.014); catalogued as rs774263160; called by muse, mutect2
- UBE2J1 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 43/448 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs764981521; called by muse, mutect2
- UBQLN3 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1452199605; called by muse, mutect2, varscan2
- UNC13C | c.6448G>T p.G2150* | Nonsense Mutation (SNP) | VAF 35/382 reads (9%) | catalogued as COSV52876360; called by muse, mutect2
- UNC5A | c.1462G>C p.V488L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as rs780065528, COSV52839901; called by muse, mutect2, varscan2
- UNC5D | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV54796266, COSV54830226; called by muse, mutect2
- UPK1A | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55878413; called by muse, mutect2, varscan2
- USO1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs752225678, COSV53705539, COSV53711127; called by mutect2, varscan2
- USP13 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 27/226 reads (12%) | catalogued as rs1353033031, COSV55865787; called by muse, mutect2, varscan2
- VASN | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1325409487; called by muse, mutect2
- VNN2 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.151); catalogued as rs1391863553, COSV58472420; called by muse, mutect2
- VSIG4 | c.951C>A p.Y317* | Nonsense Mutation (SNP) | VAF 29/284 reads (10%) | catalogued as rs762489704, COSV66074248; called by muse, mutect2, varscan2
- VSX2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs780624817; called by muse, mutect2
- VWDE | c.4300G>A p.G1434S | Missense Mutation (SNP) | VAF 59/545 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368357676; called by muse, mutect2, varscan2
- WNK3 | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.492); catalogued as COSV63612134; called by muse, mutect2
- XXYLT1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs1315999615; called by muse, mutect2, varscan2
- ZAN | c.6546G>T p.Q2182H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV61806256; called by muse, mutect2, varscan2
- ZER1 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs763228963, COSV52568174; called by mutect2, varscan2
- ZFAND4 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 39/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1027350496; called by muse, mutect2
- ZFHX4 | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.1); catalogued as rs1248444058, COSV50607690; called by muse, mutect2
- ZFHX4 | c.6832C>A p.R2278S | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367963893, COSV50641875; called by muse, mutect2
- ZFP42 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58818275; called by muse, mutect2
- ZGRF1 | c.4528G>T p.E1510* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | catalogued as COSV58343211; called by muse, mutect2
- ZNF260 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101591049; called by muse, mutect2, varscan2
- ZNF335 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1426169751, COSV100532528, COSV59817318; called by muse, mutect2, varscan2
- ZNF467 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158557185, COSV100118001, COSV100118112; called by mutect2, varscan2
- ZNF536 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs373259584, COSV62821921; called by muse, mutect2, varscan2
- ZNF627 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV63141935; called by muse, mutect2, varscan2
- ZNF729 | c.2851C>G p.L951V | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV62603657; called by muse, mutect2, varscan2
- ZNF804B | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 112/690 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100303759, COSV60862576; called by muse, mutect2, varscan2
- AARS1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 19/445 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ABCA9 | c.4241T>A p.L1414Q | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.588); called by muse, mutect2
- ABCB6 | c.1407G>C p.E469D | Missense Mutation (SNP) | VAF 19/516 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- ABCG2 | c.290A>T p.K97I | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABI3BP | c.1881A>T p.Q627H | Missense Mutation (SNP) | VAF 75/613 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AC011005.1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ACACA | c.2359G>T p.D787Y | Missense Mutation (SNP) | VAF 89/610 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACAP3 | c.1876G>T p.G626C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ACBD4 | c.574-1G>A p.X192_splice (on ENST00000376955 / NM_001378111.1; = p.E195K on NM_024722.4) | Splice Site (SNP) | VAF 26/189 reads (14%) | called by muse, mutect2, varscan2
- ACCSL | c.8A>T p.H3L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by mutect2, varscan2
- ACP4 | c.578C>A p.T193K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACP4 | c.884T>A p.L295H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP7 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by mutect2, varscan2
- ACVRL1 | c.679G>T p.A227S | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM21 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 14/332 reads (4%) | called by muse, mutect2
- ADAM23 | c.1545G>T p.E515D | Missense Mutation (SNP) | VAF 23/436 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2
- ADARB1 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- ADIPOQ | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ADIPOQ | c.546G>C p.M182I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2
- ADRB3 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- AGAP1 | c.801+1del | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by mutect2, pindel, varscan2
- AGBL2 | c.2654G>C p.R885T | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- AGRN | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- AHNAK2 | c.4273G>A p.D1425N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- AHR | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AHSG | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- AK5 | c.1529C>A p.T510N (on ENST00000354567 / NM_174858.3; = p.T484N on NM_012093.4) | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALMS1 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- ALS2 | c.777A>T p.L259F | Missense Mutation (SNP) | VAF 77/670 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ANAPC15 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 29/282 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANK2 | c.8780C>A p.P2927H | Missense Mutation (SNP) | VAF 54/744 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD17 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2
- ANKRD18B | c.2540A>T p.E847V | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, varscan2
- ANKRD30A | c.3305A>T p.H1102L (on ENST00000611781; = p.H1046L on NM_052997.2) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by mutect2, varscan2
- ANKRD31 | c.5243G>T p.W1748L | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ANKRD33B | c.434A>T p.H145L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD36C | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANTXRL | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- APOB | c.4022C>A p.T1341N | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP21 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP36 | c.1630T>A p.Y544N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ARID5B | c.3088del p.A1030Qfs*5 | Frame Shift Del (DEL) | VAF 17/138 reads (12%) | called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.700A>T p.R234* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ASMTL | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATIC | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- ATP2C1 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 58/736 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ATR | c.6499G>T p.V2167L | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AXIN1 | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- BAZ1A | c.2389A>G p.I797V | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2
- BAZ2B | c.2902A>T p.K968* | Nonsense Mutation (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- BCAT1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- BCL10 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- BNC2 | c.1024G>T p.G342W | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRDT | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- BRINP1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 71/477 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BTN2A1 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 34/538 reads (6%) | called by muse, mutect2
- C10orf71 | c.482G>T p.R161M | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2
- C15orf39 | c.22A>T p.R8* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- C17orf50 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- C1orf141 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- C4orf54 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2
- CACNG3 | c.41C>A p.T14N | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CALCA | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CAPN5 | c.1188G>T p.E396D (on ENST00000456580; = p.E356D on NM_004055.5) | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- CARD11 | c.1906G>T p.V636F | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, varscan2
- CARD17 | c.331T>G p.*111Eext*33 | Nonstop Mutation (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- CASP12 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 41/459 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.219); called by muse, mutect2
- CASTOR1 | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CCDC154 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- CCDC168 | c.16429G>A p.E5477K | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.731); called by muse, mutect2
- CCDC168 | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CCIN | c.1622C>A p.T541K | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCNB3 | c.1341G>T p.E447D | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- CCNT1 | c.1741G>T p.G581* | Nonsense Mutation (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- CCR5 | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD320 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- CD47 | c.266C>G p.S89* | Nonsense Mutation (SNP) | VAF 22/582 reads (4%) | called by muse, mutect2
- CDH11 | c.55C>A p.H19N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH7 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 41/578 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2
- CDK16 | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDRT1 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CENPF | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP295 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- CEP97 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2
- CES1 | c.822C>A p.C274* | Nonsense Mutation (SNP) | VAF 44/898 reads (5%) | called by muse, mutect2
- CFAP47 | c.4172T>A p.V1391E | Missense Mutation (SNP) | VAF 19/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CHAT | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHGA | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.135); called by muse, varscan2
- CHML | c.1922del p.S641Lfs*7 | Frame Shift Del (DEL) | VAF 69/518 reads (13%) | called by mutect2, pindel, varscan2
- CHRM2 | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 79/534 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CHRNA4 | c.927C>G p.Y309* | Nonsense Mutation (SNP) | VAF 64/398 reads (16%) | called by muse, mutect2, varscan2
- CHRND | c.1053C>A p.F351L | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); called by muse, varscan2
- CIAO1 | c.60G>T p.W20C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTRL | c.5458G>T p.E1820* | Nonsense Mutation (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- COL11A1 | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 44/592 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- COL11A2 | c.1987C>G p.Q663E (on ENST00000341947 / NM_080680.3; = p.Q556E on NM_080679.2) | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2
- COL14A1 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.435); called by muse, mutect2
- COL1A2 | c.2788C>G p.P930A | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.056); called by muse, mutect2
- COL3A1 | c.2229+1G>T p.X743_splice | Splice Site (SNP) | VAF 62/500 reads (12%) | called by muse, mutect2, varscan2
- COLEC12 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.478); called by muse, varscan2
- COP1 | c.1187T>G p.L396W | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- COQ2 | c.822C>G p.I274M | Missense Mutation (SNP) | VAF 45/602 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.193); called by muse, mutect2
- CORIN | c.1389C>A p.C463* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- CPO | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRP | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, varscan2
- CRPPA | c.961G>T p.G321C (on ENST00000407010 / NM_001368197.1; = p.G271C on NM_001101417.4) | Missense Mutation (SNP) | VAF 66/528 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBG3 | c.2705G>T p.G902V | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2
- CSMD1 | c.7266A>T p.K2422N (on ENST00000520002; = p.K2421N on NM_033225.6) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); called by muse, mutect2
- CSPG4 | c.5954C>A p.P1985H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSPP1 | c.1720G>A p.A574T (on ENST00000676605; = p.A533T on NM_024790.6) | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2
- CTAGE1 | c.490T>C p.F164L | Missense Mutation (SNP) | VAF 20/568 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- CTAGE15 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 53/1394 reads (4%) | called by muse, mutect2
- CTNNA3 | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.973); called by muse, mutect2
- CTNND2 | c.2602G>T p.G868C | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.3884G>T p.G1295V | Missense Mutation (SNP) | VAF 28/616 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CUX1 | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CWC22 | c.75G>T p.R25S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- CXorf58 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CYLD | c.2448T>G p.F816L | Missense Mutation (SNP) | VAF 15/403 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- CYP3A43 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- CYP4V2 | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- DDC | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DDX52 | c.1575A>G p.R525= | Splice Region (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- DHX33 | c.736G>T p.A246S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DIDO1 | c.1007A>T p.Q336L | Missense Mutation (SNP) | VAF 73/642 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DISP3 | c.1358A>C p.Y453S | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DKK1 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.801); called by muse, mutect2
- DKK1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2
- DLG1 | c.1883A>C p.Q628P | Missense Mutation (SNP) | VAF 67/616 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- DMXL1 | c.3605G>T p.S1202I | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DNAH11 | c.10885G>T p.E3629* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2
- DNAH5 | c.9269C>T p.P3090L | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH9 | c.10504C>A p.L3502M | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); called by muse, varscan2
- DNAI4 | c.2375G>T p.G792V | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- DNAJB6 | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DNAJC10 | c.1785G>C p.M595I | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DPP10 | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by mutect2, varscan2
- DSCAM | c.4211A>G p.N1404S | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DSP | c.5460A>T p.K1820N | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- DST | c.3283G>A p.E1095K (on ENST00000361203 / NM_001374722.1; = p.E769K on NM_001723.6) | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); called by muse, mutect2
- DTHD1 | c.954C>A p.S318R (on ENST00000456874; = p.S153R on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- DYNC2I1 | c.1469G>T p.S490I | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2
- DYNC2I1 | c.1968G>T p.M656I | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, varscan2
- DYRK2 | c.613G>A p.D205N (on ENST00000344096 / NM_006482.3; = p.D132N on NM_003583.4) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- EIF2AK3 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 57/563 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIF2AK4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF2B3 | c.1054-1G>T p.X352_splice | Splice Site (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- EML5 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 40/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ENAM | c.3171C>A p.C1057* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- ENG | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ENGASE | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EPB41L4B | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- EPHB6 | c.3013C>A p.H1005N | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- EPS8L1 | c.1486G>C p.E496Q (on ENST00000201647 / NM_133180.3; = p.E369Q on NM_017729.3) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ERCC4 | c.1735G>T p.V579F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ERVMER34-1 | c.673A>T p.N225Y | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ESPNL | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ESRP1 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2
- EXOSC7 | c.824A>C p.H275P | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- EXOSC7 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2
- F11 | c.1841A>T p.Y614F | Missense Mutation (SNP) | VAF 16/339 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.163); called by muse, mutect2
- FAM160A1 | c.2660A>T p.Q887L | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FAM181B | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47C | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.151); called by muse, mutect2
- FAM91A1 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- FAT3 | c.8059G>C p.V2687L | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.168); called by muse, mutect2
- FAT3 | c.9577C>A p.L3193M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBL | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- FBN2 | c.4208G>T p.G1403V | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO16 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- FBXO4 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- FCRL1 | c.1241G>T p.R414M | Missense Mutation (SNP) | VAF 44/378 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FCRL4 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FCRL6 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRL6 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FGF2 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2
- FLAD1 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.7159C>A p.Q2387K | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.017); called by muse, mutect2
- FLNC | c.1877G>T p.C626F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- FNDC1 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FNDC1 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOCAD | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 29/469 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- FOXN3 | c.1373G>T p.G458V (on ENST00000261302; = p.G436V on NM_005197.4) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FREM3 | c.5122C>A p.P1708T | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FRMPD1 | c.872T>A p.V291E | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD4 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2
- FRYL | c.1987-1G>C p.X663_splice | Splice Site (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- FSD1L | c.1564A>T p.S522C | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- FSIP2 | c.7642G>T p.G2548W | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- FSIP2 | c.9506C>G p.S3169* | Nonsense Mutation (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- FST | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.444); called by muse, mutect2
- FTHL17 | c.312del p.F105Sfs*49 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- FZD8 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- GABBR2 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GABBR2 | c.445T>C p.W149R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GABRA6 | c.229T>A p.Y77N | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GABRR2 | c.350G>C p.S117T | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2
- GAREM2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GAS2L2 | c.1865C>A p.P622Q | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- GCKR | c.1865C>A p.P622H | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.839); called by muse, mutect2
- GCLC | c.1090+5G>T | Splice Region (SNP) | VAF 97/661 reads (15%) | called by muse, mutect2, varscan2
- GCNT7 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 46/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCSAML | c.101C>A p.T34N | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GKN2 | c.13-2A>T p.X5_splice | Splice Site (SNP) | VAF 33/466 reads (7%) | called by muse, mutect2
- GLB1L3 | c.1228C>G p.P410A | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- GLI3 | c.4172G>T p.G1391V | Missense Mutation (SNP) | VAF 63/424 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- GLI3 | c.1146C>A p.H382Q | Missense Mutation (SNP) | VAF 28/629 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.024); called by muse, mutect2
- GLT1D1 | c.820C>A p.P274T (on ENST00000442111 / NM_001366889.1; = p.P194T on NM_144669.3) | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- GOLGA8S | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.394); called by muse, mutect2
- GPC6 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.326); called by muse, mutect2
- GPD2 | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.699); called by muse, mutect2
- GRIA3 | c.1013G>C p.G338A | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2
- GRID2IP | c.1365G>T p.E455D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2
- GRIN3A | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 106/625 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM8 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 61/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRM8 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSAP | c.2249G>T p.S750I | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- GSK3B | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GTF2A1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 32/431 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2
- H1-8 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.216); called by muse, mutect2
- H3-3A | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C3 | c.187A>G p.I63V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HACE1 | c.405A>G p.I135M | Missense Mutation (SNP) | VAF 40/672 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- HBB | c.106T>A p.Y36N | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- HDAC6 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HEATR9 | c.1641G>C p.R547S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2
- HEMK1 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- HEPACAM | c.709+1G>T p.X237_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- HEPHL1 | c.2370T>A p.Y790* | Nonsense Mutation (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- HERC2P3 | n.337G>T | Splice Region (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- HGF | c.528C>G p.Y176* | Nonsense Mutation (SNP) | VAF 65/411 reads (16%) | called by muse, mutect2, varscan2
- HHLA1 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2
- HK1 | c.706G>C p.A236P | Missense Mutation (SNP) | VAF 40/561 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HLA-E | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.13590G>T p.E4530D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- HNF4A | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); called by muse, varscan2
- HOXC5 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.118); called by muse, mutect2
- HOXD13 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- HSPA1L | c.1690A>G p.I564V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- HUWE1 | c.10720T>A p.S3574T | Missense Mutation (SNP) | VAF 43/595 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- HUWE1 | c.10282G>T p.A3428S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- ICE2 | c.1717A>T p.T573S | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- IGHM | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.04); called by mutect2, varscan2
- IGHV3OR16-8 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGKV1-16 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 77/621 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- IGKV3-11 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 46/457 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- IGSF8 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1226C>A p.T409K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INHBE | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- INIP | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- INPP5B | c.2783A>C p.K928T (on ENST00000373023; = p.K848T on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- INSL5 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- IPO13 | c.1673G>T p.C558F | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IQUB | c.1048A>T p.R350W | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IRF4 | c.638-2A>T p.X213_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ISX | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ITGA1 | c.1700G>T p.C567F | Missense Mutation (SNP) | VAF 57/433 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- ITGA1 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 34/277 reads (12%) | called by muse, mutect2, varscan2
- JHY | c.1562G>T p.G521V | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); called by muse, mutect2
- KALRN | c.7586G>T p.G2529V (on ENST00000360013 / NM_001024660.4; = p.G832V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KCNB2 | c.1698G>T p.R566S | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.042); called by muse, mutect2
- KCNC2 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2
- KCNH2 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNH8 | c.1575+6G>T | Splice Region (SNP) | VAF 41/257 reads (16%) | called by muse, mutect2, varscan2
- KCNK10 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2
- KCNT2 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCP | c.3563T>A p.V1188E (on ENST00000620378; = p.V1312E on NM_001366122.1) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM4B | c.627-1G>T p.X209_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- KDM4B | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1755 | c.231C>A p.H77Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- KIF1A | c.4679C>A p.A1560E (on ENST00000320389 / NM_001379639.1; = p.A1552E on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- KIF1B | c.4426G>T p.E1476* (on ENST00000377086 / NM_001365952.1; = p.E1430* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2
- KIF21B | c.3812A>T p.D1271V | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KIF5B | c.2205-2A>T p.X735_splice | Splice Site (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- KIF5C | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- KIR2DL3 | c.998A>C p.Y333S | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIR3DL2 | c.859C>A p.H287N | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- KMT2A | c.7132G>A p.D2378N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- KMT2E | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- KNDC1 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- KNG1 | c.1514A>C p.K505T | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- KRI1 | c.482A>T p.K161M | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KRT33B | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT40 | c.557A>T p.Q186L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- KRTAP10-4 | c.371G>T p.C124F | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); called by muse, mutect2
- KRTAP9-1 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.07); called by muse, mutect2, varscan2
- L1CAM | c.1959G>T p.E653D | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- L3MBTL3 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMA1 | c.8383G>C p.G2795R | Missense Mutation (SNP) | VAF 50/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAMA1 | c.5352G>T p.M1784I | Missense Mutation (SNP) | VAF 45/476 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- LAMB4 | c.3768G>T p.M1256I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- LAMB4 | c.3330C>A p.C1110* | Nonsense Mutation (SNP) | VAF 44/359 reads (12%) | called by muse, mutect2, varscan2
- LAMC3 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LCA5L | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.397); called by muse, mutect2
- LEPR | c.2236G>T p.A746S | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- LHX8 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRA2 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- LIN9 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- LINGO2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LLGL1 | c.1003G>T p.D335Y | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LLGL2 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMOD3 | c.364A>C p.K122Q | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LRBA | c.8456G>T p.G2819V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- LRP1B | c.12880C>T p.Q4294* | Nonsense Mutation (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2, varscan2
- LRRC53 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 37/403 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LRRC72 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- LRRIQ4 | c.879C>A p.H293Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- LST1 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- MAGEB5 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 14/259 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- MAGEB6 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2
- MALRD1 | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MAOB | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP2K5 | c.1102-4G>T | Splice Region (SNP) | VAF 48/289 reads (17%) | called by muse, mutect2, varscan2
- MAP4K5 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2
- MAPK8IP2 | c.1825C>A p.H609N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- MCF2 | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MCF2 | c.965G>T p.S322I | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MCF2 | c.335T>G p.L112* | Nonsense Mutation (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- MCF2 | c.154G>A p.G52S (on ENST00000520602; = p.G9S on NM_001099855.1) | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ME1 | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- MED12 | c.5597A>T p.Q1866L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MEFV | c.1607A>T p.H536L | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2
- MEOX2 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MFSD6 | c.2084G>T p.W695L | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MICAL3 | c.837G>T p.R279S | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.073); called by mutect2, varscan2
- MMP16 | c.1535A>G p.N512S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- MMP2 | c.1384G>T p.G462C | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- MMS19 | c.2002C>G p.L668V | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MOGAT2 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- MOGAT3 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MON2 | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- MPHOSPH8 | c.213+1del | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel
- MROH2B | c.4628T>A p.L1543Q | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- MRPL1 | c.938A>T p.K313I | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- MRS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MSI2 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.706); called by mutect2, varscan2
- MTFP1 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- MTREX | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MUC16 | c.27612C>A p.S9204R | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MXRA5 | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MYADML2 | c.573C>G p.Y191* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- MYH1 | c.4031G>C p.C1344S | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MYLK | c.2289dup p.D764Rfs*11 | Frame Shift Ins (INS) | VAF 57/498 reads (11%) | called by mutect2, pindel, varscan2
- MYO18B | c.5722C>G p.Q1908E | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MYO5C | c.909G>C p.M303I | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- MYO7A | c.2188-1G>T p.X730_splice | Splice Site (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- MYOM3 | c.2887C>A p.L963I | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.196); called by muse, mutect2
- NAALAD2 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NBPF10 | c.1904C>A p.S635* | Nonsense Mutation (SNP) | VAF 79/705 reads (11%) | called by muse, mutect2, varscan2
- NBPF6 | c.1793T>A p.L598Q | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- NCL | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- NEGR1 | c.314T>A p.I105K | Missense Mutation (SNP) | VAF 62/598 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NFATC3 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2
- NGFR | c.169T>A p.C57S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NLGN4X | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- NLRP13 | c.2248C>G p.L750V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NLRP5 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NOBOX | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); called by muse, mutect2
- NOL11 | c.1054+2T>A p.X352_splice | Splice Site (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- NPFFR2 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 41/546 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- NRXN3 | c.3244G>T p.G1082* (on ENST00000335750 / NM_001330195.2; = p.G709* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 43/558 reads (8%) | called by muse, mutect2
- NRXN3 | c.271A>T p.K91* (on ENST00000557594 / NM_001272020.2; = p.K723* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- NRXN3 | c.1845G>T p.K615N (on ENST00000557594 / NM_001272020.2; = p.K1039N on NM_004796.6) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NTN1 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- NTN5 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUP93 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); called by muse, mutect2
- NWD2 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OGT | c.582G>T p.W194C | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OLAH | c.400C>A p.H134N (on ENST00000378228 / NM_001039702.3; = p.H187N on NM_018324.3) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OLFM4 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 78/555 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OPHN1 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- OPRK1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- OR13F1 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- OR14A16 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- OR1L3 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR1L4 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2M5 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR2T10 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 69/369 reads (19%) | called by muse, mutect2, varscan2
- OR2T35 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- OR4C12 | c.839T>A p.L280* | Nonsense Mutation (SNP) | VAF 51/305 reads (17%) | called by muse, mutect2, varscan2
- OR4C13 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- OR4D5 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2
- OR4F6 | c.775A>T p.I259F | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR51V1 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5I1 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 44/419 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OR6C76 | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR6K3 | c.311A>G p.E104G (on ENST00000368146; = p.E88G on NM_001005327.2) | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR6Y1 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 41/462 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8H2 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 37/394 reads (9%) | called by muse, mutect2, varscan2
- OTOF | c.3635T>G p.F1212C (on ENST00000272371 / NM_194248.3; = p.F465C on NM_004802.4) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOF | c.3368C>A p.P1123H (on ENST00000272371 / NM_194248.3; = p.P376H on NM_004802.4) | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOL1 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.273); called by muse, mutect2
- PABPC5 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAIP1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PAPLN | c.1541G>T p.G514V (on ENST00000554301; = p.G487V on NM_173462.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PARD3B | c.1556G>T p.R519I | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- PAX3 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PCDH15 | c.4999C>A p.P1667T | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PCDHAC2 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDP2 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- PDZD2 | c.5918C>T p.S1973L | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PGAP3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PHF14 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 20/421 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); called by muse, mutect2
- PHLDB2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 37/353 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PHYKPL | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PIGN | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3CB | c.2779G>A p.V927I | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PKD1L1 | c.8383C>A p.L2795M | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PKD2L1 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- PKN2 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLD5 | c.715G>T p.D239Y (on ENST00000442594; = p.D177Y on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PLEKHA4 | c.263A>T p.K88M | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLSCR4 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 68/530 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PNMA3 | c.1345G>C p.G449R | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PNMA3 | c.1346G>T p.G449V | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PNPLA3 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 54/443 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- POC1B | c.115dup p.D39Gfs*14 | Frame Shift Ins (INS) | VAF 11/129 reads (9%) | called by mutect2, pindel
- POLRMT | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- POM121L12 | c.50del p.K17Rfs*17 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- POTEB3 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by mutect2, varscan2
- POTEE | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 52/580 reads (9%) | called by muse, mutect2
- POU3F3 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- POU4F1 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PPFIA2 | c.2159G>T p.S720I | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PPFIA2 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PPIP5K2 | c.1560G>T p.R520S | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PPP2R3A | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 67/570 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP3R1 | c.11A>T p.E4V | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- PPP4R3A | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 24/664 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2
- PPP4R3C | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 37/569 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.607); called by muse, mutect2
- PRL | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PRPF8 | c.5664G>T p.E1888D | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.633); called by muse, varscan2
- PRSS12 | c.1766G>T p.C589F | Missense Mutation (SNP) | VAF 36/680 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSG9 | c.173T>G p.L58W | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTGFRN | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
646 further variants in this file (186 protein-altering or splice-affecting, 288 silent, 172 other) are not listed here.
